Somatic mutation profile of tumor specimen MBCProject_0698_T1_WES (aliquot MBCProject_0698_T1_WES_1) from CMI case MBCProject_0698, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 44.6 years (16,297 days).
Specimen MBCProject_0698_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4f9fb9c-b755-430d-80c3-4b60652c0ea6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0698_SALIVA (Saliva), aliquot MBCProject_0698_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a1176aa-fd7f-4623-bf2a-11a7fbdc532c

The open-access MAF lists 146 somatic variants for this specimen: 99 protein-altering or splice-affecting, 32 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 32, Intron 7, Nonsense Mutation 5, RNA 4, Frame Shift Del 3, In Frame Del 2, Splice Site 2, 5'UTR 1, Splice Region 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2B | c.1054G>C p.D352H | Missense Mutation (SNP) | VAF 149/757 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.879); catalogued as COSV63425670; called by muse, mutect2, varscan2
- ATOH8 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 57/432 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV100092503; called by muse, mutect2, varscan2
- C4orf33 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 66/655 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1025768015; called by muse, mutect2, varscan2
- CAMSAP3 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as COSV50331188; called by muse, mutect2, varscan2
- COL2A1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 43/938 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV61534911; called by muse, mutect2
- EIF2AK3 | c.1263C>G p.N421K | Missense Mutation (SNP) | VAF 24/822 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV57548001; called by muse, mutect2
- EXT1 | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 84/2186 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as CD000253; called by muse, mutect2
- FLVCR1 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 37/658 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV100875007; called by muse, mutect2
- GBA3 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 44/880 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72438265; called by muse, mutect2
- GPR17 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 70/475 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs778865404; called by muse, mutect2, varscan2
- HELZ2 | c.3704C>T p.S1235L (on ENST00000467148 / NM_001037335.2; = p.S666L on NM_033405.3) | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs531583863; called by muse, mutect2, varscan2
- HTRA1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 219/1117 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs748367895, COSV64564199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IDH3B | c.1150G>A p.G384R | Missense Mutation (SNP) | VAF 87/789 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs866632435; called by muse, mutect2, varscan2
- KATNIP | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 53/303 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs181329078, COSV55180034; called by muse, mutect2, varscan2
- MPV17L | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as rs1478272473; called by muse, mutect2, varscan2
- N4BP2 | c.5222G>C p.R1741P | Missense Mutation (SNP) | VAF 76/691 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54699897; called by muse, mutect2
- PIK3IP1 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.643); catalogued as rs1230972828; called by muse, mutect2
- PPP2R5D | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 81/597 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as COSV55144442; called by muse, mutect2, varscan2
- PRKG1 | c.1513C>G p.L505V | Missense Mutation (SNP) | VAF 48/388 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV64767295, COSV64771514; called by muse, varscan2
- PRODH2 | c.1141G>C p.G381R (on ENST00000301175; = p.G305R on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/689 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56558987; called by muse, mutect2
- PRPF40A | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 31/606 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV68357059; called by muse, mutect2
- PTPRU | c.1238G>C p.R413P | Missense Mutation (SNP) | VAF 117/818 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60536048; called by muse, mutect2, varscan2
- SEC31B | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 37/717 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV64824662; called by muse, mutect2
- SFXN4 | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758272461; called by muse, mutect2, varscan2
- SHROOM3 | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 20/584 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99935197; called by muse, mutect2
- SQSTM1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1376781573; called by muse, mutect2
- AC090517.4 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- AFF3 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- AFTPH | c.2367G>A p.M789I | Missense Mutation (SNP) | VAF 36/444 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- ALPK3 | c.3128T>C p.L1043P | Missense Mutation (SNP) | VAF 19/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- APPBP2 | c.226dup p.R76Kfs*17 | Frame Shift Ins (INS) | VAF 47/422 reads (11%) | called by mutect2, pindel, varscan2
- ARHGAP22 | c.317G>T p.S106I | Missense Mutation (SNP) | VAF 81/418 reads (19%) | SIFT tolerated (0.72); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BDH1 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 34/824 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- C11orf16 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 72/503 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf131 | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 38/291 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CAD | c.6516G>C p.M2172I | Missense Mutation (SNP) | VAF 22/500 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, mutect2
- CDH15 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2
- CEP112 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 30/414 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- CEP192 | c.7509_7516del p.F2503Lfs*7 | Frame Shift Del (DEL) | VAF 33/381 reads (9%) | called by mutect2, pindel
- CLCNKA | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 84/649 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CNTRL | c.4712C>G p.S1571C | Missense Mutation (SNP) | VAF 20/607 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- CSF3R | c.2276C>A p.P759H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2
- DBT | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 109/890 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- E2F4 | c.616_627del p.A206_V209del | In Frame Del (DEL) | VAF 63/491 reads (13%) | called by mutect2, pindel
- ELF4 | c.1712G>C p.R571T | Missense Mutation (SNP) | VAF 38/572 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ERGIC2 | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- ESRRG | c.749A>C p.Y250S | Missense Mutation (SNP) | VAF 40/276 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- FAH | c.924G>T p.M308I | Missense Mutation (SNP) | VAF 47/1183 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.054); called by muse, mutect2
- FLAD1 | c.1747C>G p.R583G | Missense Mutation (SNP) | VAF 56/538 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNIP2 | c.2307A>C p.K769N | Missense Mutation (SNP) | VAF 89/772 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR84 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 56/556 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2
- HPRT1 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 20/648 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2
- HSD17B12 | c.536+6T>A | Splice Region (SNP) | VAF 31/252 reads (12%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1020G>C p.E340D | Missense Mutation (SNP) | VAF 28/808 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2
- IGSF9B | c.1388G>T p.S463I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- IL1RL2 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- IL31 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 22/594 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ILDR2 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2
- ISLR2 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 49/397 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KALRN | c.5797G>T p.V1933F (on ENST00000360013 / NM_001024660.4; = p.V236F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/417 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- KBTBD11 | c.830C>G p.S277W | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KIAA1549L | c.964C>A p.P322T (on ENST00000321505; = p.P619T on NM_012194.3) | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- KIDINS220 | c.1961C>T p.T654I | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.898); called by muse, mutect2
- KSR2 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 122/1035 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- KTI12 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 51/437 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMB1 | c.3248del p.P1083Hfs*106 | Frame Shift Del (DEL) | VAF 30/285 reads (11%) | called by mutect2, pindel, varscan2
- LRP1B | c.8360G>C p.C2787S | Missense Mutation (SNP) | VAF 27/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MED16 | c.2086C>G p.L696V | Missense Mutation (SNP) | VAF 50/330 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, varscan2
- METRN | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- MICAL2 | c.5422-2A>G p.X1808_splice | Splice Site (SNP) | VAF 98/941 reads (10%) | called by muse, mutect2, varscan2
- MINAR1 | c.2740A>G p.M914V | Missense Mutation (SNP) | VAF 38/772 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.191); called by muse, mutect2
- MLXIP | c.2752G>C p.E918Q | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.343); called by muse, mutect2
- MUC5B | c.5225C>A p.T1742N | Missense Mutation (SNP) | VAF 76/420 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- MYLK2 | c.1606G>C p.A536P | Missense Mutation (SNP) | VAF 120/1106 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NEDD4 | c.2339G>A p.R780K (on ENST00000508342 / NM_001284338.1; = p.R361K on NM_006154.4) | Missense Mutation (SNP) | VAF 42/476 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2
- NES | c.4359G>C p.Q1453H | Missense Mutation (SNP) | VAF 42/546 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- NIPAL2 | c.123C>A p.Y41* | Nonsense Mutation (SNP) | VAF 61/245 reads (25%) | called by muse, mutect2, varscan2
- NMT2 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 26/271 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- PALB2 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 118/615 reads (19%) | called by muse, mutect2, varscan2
- PAXIP1 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 28/359 reads (8%) | called by muse, mutect2
- PSAPL1 | c.607A>T p.T203S | Missense Mutation (SNP) | VAF 67/527 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGIS | c.996G>C p.Q332H | Missense Mutation (SNP) | VAF 23/584 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2
- PTPRN2 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, varscan2
- PUM2 | c.3010C>T p.Q1004* | Nonsense Mutation (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- RMND5A | c.556C>G p.Q186E | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.098); called by muse, mutect2
- SETD2 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2
- SLC7A11 | c.1349C>T p.T450I | Missense Mutation (SNP) | VAF 56/518 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SLITRK2 | c.2402C>A p.T801N | Missense Mutation (SNP) | VAF 24/694 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2
- SUPT20H | c.232G>A p.V78I (on ENST00000350612 / NM_001014286.3; = p.V79I on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/807 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TBX15 | c.1114_1122del p.P372_T374del (on ENST00000369429 / NM_001330677.2; = p.P266_T268del on NM_152380.3) | In Frame Del (DEL) | VAF 108/1046 reads (10%) | called by mutect2, pindel
- TBX3 | c.643_657+2del p.X215_splice | Splice Site (DEL) | VAF 164/1477 reads (11%) | called by mutect2, pindel
- TCFL5 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2
- TENM4 | c.5707G>A p.E1903K | Missense Mutation (SNP) | VAF 46/698 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2
- TMIGD3 | c.696G>C p.L232F (on ENST00000369717 / NM_001081976.2; = p.L313F on NM_020683.7) | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TP53 | c.254_293del p.P85Lfs*25 | Frame Shift Del (DEL) | VAF 56/364 reads (15%) | called by mutect2, pindel
- TSPOAP1 | c.4190C>G p.P1397R | Missense Mutation (SNP) | VAF 42/625 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.296); called by muse, mutect2
- VNN1 | c.114T>A p.N38K | Missense Mutation (SNP) | VAF 22/615 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- ZKSCAN3 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 57/464 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF285 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- AARS2 | c.2880G>A p.V960= | Silent (SNP) | VAF 103/772 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP30 | c.1188C>T p.I396= | Silent (SNP) | VAF 18/417 reads (4%) | called by muse, mutect2
- ARMCX2 | c.807G>A p.P269= | Silent (SNP) | VAF 92/903 reads (10%) | catalogued as rs782805456, COSV57531631; called by muse, mutect2
- C11orf16 | c.513C>A p.G171= | Silent (SNP) | VAF 72/508 reads (14%) | called by muse, mutect2, varscan2
- C2 | c.2220G>A p.R740= | Silent (SNP) | VAF 48/835 reads (6%) | called by muse, mutect2
- CACNA1F | c.2544C>A p.G848= | Silent (SNP) | VAF 82/643 reads (13%) | called by muse, varscan2
- COPZ2 | c.150C>T p.F50= | Silent (SNP) | VAF 24/511 reads (5%) | called by muse, mutect2
- DSPP | c.393C>T p.I131= | Silent (SNP) | VAF 60/893 reads (7%) | called by muse, mutect2
- FAM221B | c.291C>A p.P97= | Silent (SNP) | VAF 85/674 reads (13%) | called by muse, mutect2, varscan2
- FAT1 | c.9948C>T p.S3316= | Silent (SNP) | VAF 94/692 reads (14%) | catalogued as rs556166660, COSV71675418; called by muse, mutect2, varscan2
- FLNA | c.2412C>A p.V804= | Silent (SNP) | VAF 38/395 reads (10%) | called by muse, mutect2
- GRM7 | c.2544C>T p.I848= | Silent (SNP) | VAF 56/1316 reads (4%) | catalogued as COSV63135718; called by muse, mutect2
- IL6R | c.444C>G p.L148= | Silent (SNP) | VAF 54/1222 reads (4%) | catalogued as rs1352622176; called by muse, mutect2
- JAK1 | c.3456T>A p.L1152= | Silent (SNP) | VAF 54/366 reads (15%) | called by muse, mutect2, varscan2
- MAFK | c.273G>A p.E91= | Silent (SNP) | VAF 54/696 reads (8%) | called by muse, mutect2
- MLXIP | c.2370C>G p.L790= | Silent (SNP) | VAF 11/263 reads (4%) | called by muse, mutect2
- MUC17 | c.2715T>C p.S905= | Silent (SNP) | VAF 35/254 reads (14%) | called by muse, mutect2, varscan2
- MYO1D | c.2574C>G p.L858= | Silent (SNP) | VAF 20/366 reads (5%) | catalogued as COSV59011401, COSV59014509; called by muse, mutect2
- NCOR1 | c.2929C>A p.R977= | Silent (SNP) | VAF 48/626 reads (8%) | called by muse, mutect2
- NOXA1 | c.222C>A p.G74= | Silent (SNP) | VAF 48/451 reads (11%) | called by muse, mutect2, varscan2
- PDXDC1 | c.324G>A p.E108= | Silent (SNP) | VAF 36/1198 reads (3%) | called by muse, mutect2
- PLOD2 | c.2151G>A p.L717= | Silent (SNP) | VAF 51/383 reads (13%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.960G>C p.R320= | Silent (SNP) | VAF 28/246 reads (11%) | called by muse, mutect2, varscan2
- PSD3 | c.2409G>A p.K803= (on ENST00000440756; = p.K802= on NM_015310.4) | Silent (SNP) | VAF 36/434 reads (8%) | called by muse, mutect2
- RABL6 | c.2103G>A p.R701= | Silent (SNP) | VAF 23/190 reads (12%) | catalogued as rs1034993410; called by muse, mutect2, varscan2
- SLC4A3 | c.27C>T p.P9= | Silent (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- SLC6A3 | c.1167G>T p.L389= | Silent (SNP) | VAF 38/1034 reads (4%) | called by muse, mutect2
- SNRNP70 | c.315C>G p.L105= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- SYMPK | c.156C>T p.I52= | Silent (SNP) | VAF 54/603 reads (9%) | called by muse, mutect2
- TRPM1 | c.1857A>T p.A619= | Silent (SNP) | VAF 173/1246 reads (14%) | called by muse, mutect2, varscan2
- WDR37 | c.321C>G p.L107= | Silent (SNP) | VAF 74/516 reads (14%) | catalogued as COSV54131634; called by muse, mutect2, varscan2
- ZCCHC7 | c.105C>G p.L35= | Silent (SNP) | VAF 59/538 reads (11%) | catalogued as rs1454582267; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2947G>A | Intron (SNP) | VAF 106/897 reads (12%) | catalogued as rs747921046, COSV58442745; called by muse, mutect2, varscan2
- C9orf163 | n.1298G>C | RNA (SNP) | VAF 54/722 reads (7%) | called by muse, mutect2
- CLYBL | chr13:99606680 C>G | 5'Flank (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- CST9LP1 | n.372C>T | RNA (SNP) | VAF 26/361 reads (7%) | called by muse, mutect2
- HOXC10 | chr12:53991768 G>C | 3'Flank (SNP) | VAF 18/139 reads (13%) | called by muse, mutect2, varscan2
- KALRN | c.7194-653G>A | Intron (SNP) | VAF 27/174 reads (16%) | called by muse, varscan2
- KIR3DX1 | n.135G>A | RNA (SNP) | VAF 60/519 reads (12%) | called by muse, mutect2, varscan2
- LEPR | c.2673+3188A>C | Intron (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- LRP5L | n.162G>C | RNA (SNP) | VAF 40/614 reads (7%) | called by muse, mutect2
- MRPS18A | c.377-46C>G | Intron (SNP) | VAF 5/54 reads (9%) | called by muse, mutect2
- PHACTR1 | c.251-119579G>T | Intron (SNP) | VAF 56/1058 reads (5%) | called by muse, mutect2
- PLEKHM1 | c.*727A>C | 3'UTR (SNP) | VAF 19/179 reads (11%) | catalogued as rs1415695371; called by muse, mutect2
- SDHA | c.1794+165C>T | Intron (SNP) | VAF 62/1008 reads (6%) | catalogued as rs201097697; called by muse, mutect2
- SFTPA2 | c.-23-28G>A | Intron (SNP) | VAF 33/275 reads (12%) | called by muse, mutect2, varscan2
- ZEB2 | c.-122G>A | 5'UTR (SNP) | VAF 38/490 reads (8%) | called by muse, mutect2
